Surgical pathology report (de-identified scan), TCGA case TCGA-24-2271, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2271-01A (Primary Tumor).

[page 1 of 4]
TCGA-24-2271

SURGICAL PATHOLOGY REPORT

Patient Name			
Address		Service	Accession
		Location:	Taken:
Gender:		MRN:	Received:
DOB:		Hospital #	Reported:
Physician(s):		Patient Type:	

Other Related Clinical Data:

DIAGNOSIS: OMENTUM, EXCISION

- PAPILLARY SEROUS ADENOCARCINOMA
- SEE COMMENT

SOFT TISSUE, ANTERIOR CUL-DE-SAC NODULE, BIOPSY

- PAPILLARY SEROUS ADENOCARCINOMA

SOFT TISSUE, "RIGHT ADNEXA", EXCISION

- PAPILLARY SEROUS ADENOCARCINOMA
- EXTENSIVE LYMPHVASCULAR SPACE INVASION IDENTIFIED
- SEE COMMENT

SOFT TISSUE, "LEFT ADNEXA", EXCISION

- PAPILLARY SEROUS ADENOCARCINOMA
- EXTENSIVE LYMPHVASCULAR SPACE INVASION IDENTIFIED
- SEE COMMENT

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Intraoperative Consultation: FS1, cul de sac nodule, biopsy - "poorly-differentiated adenocarcinoma,"

Microscopic Description and Comment: Sections of the omentum show diffuse involvement by moderate to poorly differentiated papillary serous adenocarcinoma. Although in many areas the tumor grows as sheets of cells, there are regions in which it

[page 2 of 4]
[REDACTED]

forms small papillary structures with epithelial tufting, and psammoma bodies are easily identified.

Sections of the anterior cul-de-sac nodule also show papillary serous adenocarcinoma.

Sections of the specimens submitted as "right adnexa" and "left adnexa" show extensive papillary serous adenocarcinoma involving fibrovascular tissue and adipose tissue. At both sites, extensive lymphovascular space invasion by tumor is present. Consistent with the lack of ovarian parenchyma on gross examination, microscopic examination of these extensively sampled specimens also shows no evidence of ovarian parenchyma. We do note that a short segment of fallopian tube is present in the section from the specimen labelled "left adnexa", with surface involvement by papillary serous adenocarcinoma. Sections of the "left adnexa" also show an organizing thrombus in a medium sized vein.

Based on the extensive involvement of the omentum, and the small size and lack of ovarian parenchyma in the specimens submitted as the adnexa, it appears that this papillary serous adenocarcinoma represents a primary peritoneal neoplasm. [REDACTED] selected slides and concurs. This case was discussed with Dr. [REDACTED]

History: The patient is a [REDACTED] who has abdominal ascites and an increased CA125. [REDACTED] is status post TAH/BSO. Operative procedure: Laparotomy, bilateral salpingo-oophorectomy, and omentectomy.

Specimen(s) Received:

- A: ANTERIOR CUL DE SAC NODULE
- B: RIGHT ADNEXA
- C: LEFT ADNEXA
- D: OMENTUM

Gross Description The specimens are received in four formalin-filled containers, each labeled with the patient's name. The first is additionally labeled "#1, anterior cul de sac nodule" and contains two gray-tan tissues with attached mature adipose tissue measuring 3.5 x 2.3 x 0.5 and 3.5 x 1.5 x 0.5 cm. The tan-gray surfaces show multinodular, finely granular areas. Also received in the container is a white unlabeled cassette which holds two fragments of tan-gray tissue with attached mature adipose tissue measuring 2.5 x 0.7 x 0.3 and 1.5 x 0.5 x 0.3 cm. The contents of this cassette are labeled A1 - FS1. Sections from each fragment are submitted in cassettes A2-A3. [REDACTED]

The second container is labeled "#2, right adnexa" and contains a fragment of tubular structure measuring 2.5 x 1.5 cm with an attached, irregular, tan-gray tissue fragment with areas of papillary projection, covered by finely granular tissue measuring 3 x 3 x 2 cm. Also received is another fragment of irregular, tan-gray tissue with papillary projections, measuring 2 x 1 x 1 cm. No normal ovarian parenchyma is identified in serial sections. Sectioning through adjacent tissue reveals gray-white, ill-defined areas in continuity with the putative tubular structure and attached tissue. [REDACTED]

The third container is labeled "#3, left adnexa" and contains a single fragment of irregular, tan-hemorrhagic tissue measuring 4 x 4 x 2 cm. The surface contains multiple papillary projections lined by finely granular areas. Serial sections show no evidence of ovarian parenchyma, but do show a tube-like tissue at the surface, measuring 2.5 cm in length with 0.5 cm diameter. Labeled C1 - presumed tube; C2-C4 - tissue with micropapillary projections. [REDACTED]

[page 3 of 4]
[REDACTED] [REDACTED]

The fourth container is labeled "#4, omentum" and holds two fragments of irregular tissue measuring 18 x 8 x 4 cm and 8 x 4 x 3 cm. The specimens are virtually replaced by tumor, and their outer surfaces are irregular, with areas of polypoid and micropapillary projections throughout. Serial sections show massive areas of gray-white, homogeneous tumor admixed with focal areas of fat and hemorrhage. The largest tumor nodules measure well over 3 cm in greatest dimension. [REDACTED]

[REDACTED] [REDACTED]

Synopsis SYNOPTIC REPORTING FORM 1. A neoplasm is PRESENT

2. The HISTOLOGIC DIAGNOSIS is: Serous adenocarcinoma
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are: Primary peritoneal
4. The NUCLEAR (BRODERS') GRADE of the tumor is: G2-G3 (Moderately-to-poorly differentiated)
5. Tumor involvement of the pelvic peritoneum is PRESENT.
6. Primary involvement of the omentum is PRESENT.
7. Regional lymph node metastases CANNOT BE EVALUATED.

Source: NCI Genomic Data Commons file 106b8b87-3887-40ca-93b9-e5fdeff34153 (TCGA-24-2271.87D64A93-9B08-48A5-A26E-1CC4B5AC8BDE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).